Somatic mutation profile of tumor specimen MMRF_1324_2_BM_CD138pos (aliquot MMRF_1324_2_BM_CD138pos_T1_KBS5U_L05836) from MMRF case MMRF_1324, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.7 years (22,526 days).
Specimen MMRF_1324_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc567093-e704-4801-bb83-26e349b8d90e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1324_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1324_1_PB_Whole_C2_KAS5U_L01614; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63954134-71ef-4cb9-a353-3083da5256bb

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FEZF2 | c.1266C>T p.C422= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1232855100, COSV51861878; called by muse, mutect2
- SYBU | c.25-240G>A | Intron (SNP) | VAF 5/37 reads (14%) | catalogued as rs973687027; called by muse, varscan2
